Surgical pathology report (de-identified scan), TCGA case TCGA-AD-A5EK, project TCGA-COAD (Colon Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-AD-A5EK-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Colon and small intestine, segmental resections:

Invasive adenocarcinoma, moderately differentiated
tumor site cannot be determined but appears to be right colon or transverse colon or hepatic flexure
tumor size = 2.5 x 2.3 x 1.0 cm
macroscopic tumor perforation - not identified
macroscopic intactness of mesorectum - not applicable
histologic type - adenocarcinoma
histologic grade - low-grade (moderately differentiated)
intra-tumoral lymphocytic response - none
peri-tumoral lymphocytic response - none
mucinous tumor component ~5%
medullary tumor component - none
tumor invades into but not through muscularis propria
all margins uninvolved by carcinoma
closest margin - 3 cm, colonic; (radial/circumferential distance = 1.5 cm)
treatment effect - not known (and none seen)
lymphovascular permeation - not seen
peri-neural invasion - not seen
tumor deposits - not identified
type of polyp - none identified
pT2, pN0 (0/11), pMx
small intestine negative for tumor

ICD-O-3

Adenocarcinoma NOS 8140/3

Path: Site: COLON, NOS C18.9

CQCF: COLON, ascending C18.2

ju
12/22/12

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Adenocarcinoma of transverse colon mass

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Right colon

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in a single formalin filled container labeled with the patient's name, and "right colon" and consists of a right hemicolectomy specimen comprised of terminal ileum (7.5 cm in length by 2.0 cm in diameter), cecum/right colon (23.0 cm in length and ranging from 3.5 up to 5.0 cm in diameter) and vermiform appendix (4.7 cm in length and ranging from 0.5 to 0.7 cm in diameter). The specimen is received stapled closed at both ends. The serosa is pink-tan, smooth to shaggy and features adherent yellow-tan mesocolonic fat. The wall averages 0.7 cm in thickness. The distal colonic mucosa is remarkable for a 2.5 x 2.3 x 1.0 cm, tan-brown, fungating mass that approaches to within 3.0 cm of the colonic margin and to within 20.0 cm of the ileal margin. On sectioning, the mass extends into but does not penetrate the muscularis and approaches to within 1.0 cm of the inked deep margin. The remainder of the mucosa is pink-tan and glistening with normal folds. No additional lesions are identified. Sections through the appendix reveal a pinpoint lumen with no discrete lesions. On section and palpation, multiple firm fatty possible lymph nodes are identified within the associated fat. They range from 0.3 up to 1.4 cm in greatest dimension.

Also received in the same container is a 2.3 cm in length by 2.7 cm in diameter segment of small bowel received stapled closed at one end and opened at the opposite end. The serosa is pink-tan and glistening with adherent yellow-tan mesenteric fat. On palpation, no lymph nodes are identified. Representative sections are submitted in cassette A1-16 labeled: Designated as follows: 1 ileal margin, en face; 2 colonic margin, en face; 3-8 entire mass to inked deep margin, perpendicular; 9 vermiform appendix; 10-11 six whole possible lymph nodes in each cassette; 12 four whole

possible lymph nodes; 13 one whole possible bisected lymph node; 14 en face opened end from separately submitted bowel segment; 15 en face stapled end from separately submitted bowel segment; 16 random full thickness sections from separately submitted bowel segment. Additionally, a yellow and green cassette are submitted for genomics research, each labeled

HPV Discrepancy		✓
Prior History		✓
Quoted Chronology Primary No. ed		✓
Reviewed	ju	12/20/12

Source: NCI Genomic Data Commons file 626062d1-a045-45e9-9b53-1509ac1c4e8b (TCGA-AD-A5EK.603C0BEB-A258-454E-970D-8ACABA1EE96D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).